Somatic mutation profile of tumor specimen C3L-06648-02 (aliquot CPT0358810009) from CPTAC case C3L-06648, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 53.6 years (19,577 days).
Specimen C3L-06648-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bcf8a46-74e9-4a6f-85bc-81d9ab300d6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06648-31 (Blood Derived Normal), aliquot CPT0358900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0009c117-c085-4cbc-8558-357fe21e54ff

The open-access MAF lists 131 somatic variants for this specimen: 94 protein-altering or splice-affecting, 33 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 33, Frame Shift Del 5, Intron 4, Splice Region 2, Nonsense Mutation 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 67/260 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13543G>A p.V4515I | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs767565751, COSV101291288, COSV68942905; called by muse, mutect2, varscan2
- ALAS2 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.055); catalogued as COSV100238742; called by muse, mutect2, varscan2
- ARC | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 66/1166 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.523); catalogued as rs931618958, COSV63079708; called by muse, mutect2
- ARHGEF10 | c.3191A>C p.K1064T (on ENST00000398564; = p.K1039T on NM_014629.4) | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.625); catalogued as rs573337230, COSV100033441; called by muse, mutect2
- BSN | c.7805G>A p.R2602H | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779319682; called by muse, mutect2
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 37/309 reads (12%) | catalogued as rs747496393; called by mutect2, pindel, varscan2
- CAAP1 | c.284T>G p.V95G | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs768547864; called by muse, mutect2, varscan2
- CACNA1D | c.1904C>T p.S635F (on ENST00000350061 / NM_001128840.3; = p.S655F on NM_000720.4) | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868210941; called by muse, mutect2, varscan2
- CENPO | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs748609442; called by muse, mutect2
- CHD5 | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52417318; called by muse, mutect2, varscan2
- CLECL1 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs762833109, COSV59931042; called by muse, mutect2, varscan2
- CSNK1G1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs769976038; called by muse, mutect2
- DCDC1 | c.4711T>G p.L1571V (on ENST00000597505 / NM_001367979.1; = p.L678V on NM_020869.3) | Missense Mutation (SNP) | VAF 23/273 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58004321; called by muse, mutect2
- DMRTC2 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.333); catalogued as rs781959531; called by muse, mutect2, varscan2
- DSCAM | c.5770T>G p.L1924V | Missense Mutation (SNP) | VAF 25/353 reads (7%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV68037014; called by muse, mutect2
- DSEL | c.1508A>G p.K503R | Missense Mutation (SNP) | VAF 67/458 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59489806, COSV59492555; called by muse, mutect2, varscan2
- FERD3L | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV51762036; called by muse, mutect2
- FOXA1 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 38/575 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51647397, COSV99163200; called by muse, mutect2
- FREM1 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750187962; called by muse, mutect2, varscan2
- GHSR | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 69/326 reads (21%) | catalogued as rs148371213; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAS1 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 78/588 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV55788543; called by muse, mutect2, varscan2
- ITFG1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs747170277, COSV57746508; called by muse, mutect2
- KCNT1 | c.1172C>T p.T391M (on ENST00000488444; = p.T410M on NM_020822.3) | Missense Mutation (SNP) | VAF 113/349 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as rs954342612, COSV53708640; called by muse, mutect2, varscan2
- KHDRBS2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 36/413 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs777332095, COSV55458478, COSV55463095; called by muse, mutect2
- LGALSL | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 51/381 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as rs375164439; called by muse, mutect2, varscan2
- LOXHD1 | c.1724T>A p.L575H | Missense Mutation (SNP) | VAF 33/494 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV59669633; called by muse, mutect2
- MAP11 | c.1127G>T p.C376F | Missense Mutation (SNP) | VAF 46/331 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1166634047; called by muse, mutect2, varscan2
- MEF2C | c.261G>A p.T87= | Splice Region (SNP) | VAF 19/220 reads (9%) | catalogued as rs777529202; ClinVar: likely benign; called by muse, mutect2
- NIPA2 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1566855952; called by muse, mutect2, varscan2
- NLRC3 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 44/636 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746010308, COSV57089565; called by muse, mutect2
- NRXN2 | c.3892G>A p.G1298R | Missense Mutation (SNP) | VAF 37/402 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1306388877; called by muse, mutect2
- OAS2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 52/469 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.264); catalogued as rs568482198, COSV60804148; called by muse, mutect2
- OR52H1 | c.604T>G p.F202V (on ENST00000322653; = p.F208V on NM_001005289.1) | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.327); catalogued as COSV59505082; called by muse, mutect2, varscan2
- OR52K1 | c.286T>G p.F96V | Missense Mutation (SNP) | VAF 43/354 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56904575; called by muse, mutect2, varscan2
- OR6P1 | c.582A>C p.Q194H | Missense Mutation (SNP) | VAF 45/427 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV58108666; called by muse, mutect2, varscan2
- OR8K3 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.966); catalogued as COSV57131412; called by muse, mutect2
- PREX2 | c.3787A>G p.R1263G | Missense Mutation (SNP) | VAF 71/294 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs529932247; called by muse, mutect2, varscan2
- RAPGEF6 | c.3548A>G p.Q1183R | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.776); catalogued as rs756994121; called by muse, mutect2, varscan2
- SEC14L5 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 76/526 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs754852146, COSV52037163; called by muse, mutect2, varscan2
- SMARCA4 | c.3557C>G p.A1186G | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60788639, COSV60811013; called by muse, mutect2
- SMOC2 | c.697G>A p.D233N (on ENST00000356284 / NM_001166412.2; = p.D244N on NM_022138.3) | Missense Mutation (SNP) | VAF 64/389 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs750297215; called by muse, mutect2, varscan2
- SORCS1 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV53862613, COSV53889165; called by muse, mutect2, varscan2
- TCERG1L | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 60/351 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201078900; called by muse, mutect2, varscan2
- TLL1 | c.1832G>T p.R611I | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV50261990; called by muse, mutect2, varscan2
- TRIM35 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 85/448 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs766380938, COSV100542833; called by muse, mutect2, varscan2
- TRPS1 | c.544G>A p.V182M (on ENST00000220888 / NM_001330599.2; = p.V195M on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/647 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1255820366; called by muse, mutect2, varscan2
- VSTM4 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 54/303 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as rs552579024; called by muse, mutect2, varscan2
- VWF | c.2695G>A p.G899S | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.457); catalogued as rs142135013; called by muse, mutect2
- ACSL5 | c.1211A>G p.K404R (on ENST00000354273; = p.K460R on NM_016234.3) | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); called by muse, mutect2
- ADCY9 | c.1207T>A p.F403I | Missense Mutation (SNP) | VAF 13/415 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADRA1D | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGBL1 | c.2263G>C p.V755L | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ASAP1 | c.704A>T p.D235V | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- CADM3 | c.238G>A p.D80N (on ENST00000368125 / NM_001127173.3; = p.D114N on NM_021189.5) | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL15A1 | c.1475C>A p.T492N | Missense Mutation (SNP) | VAF 22/544 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); called by muse, mutect2
- CRNKL1 | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DDX31 | c.1157T>A p.V386E | Missense Mutation (SNP) | VAF 24/397 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- DSE | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DSG3 | c.517+3_517+6dup | Frame Shift Ins (INS) | VAF 18/126 reads (14%) | called by mutect2, varscan2
- EML2 | c.1088G>A p.G363D | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- FCRL2 | c.988del p.I330Sfs*29 | Frame Shift Del (DEL) | VAF 91/507 reads (18%) | called by mutect2, pindel, varscan2
- FOXE1 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 17/575 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2
- FREM2 | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- HASPIN | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ICE1 | c.3663G>T p.K1221N | Missense Mutation (SNP) | VAF 67/298 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- IGHV1-18 | c.240del p.Q81Rfs*9 | Frame Shift Del (DEL) | VAF 31/287 reads (11%) | called by mutect2, pindel, varscan2
- INPPL1 | c.3703G>C p.D1235H | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIR3DL2 | c.230A>C p.Q77P | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LONRF2 | c.1946T>G p.L649R | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MAPK8IP1 | c.1919del p.Q640Rfs*2 | Frame Shift Del (DEL) | VAF 29/248 reads (12%) | called by mutect2, pindel, varscan2
- MUC6 | c.3828_3838del p.A1277Tfs*116 | Frame Shift Del (DEL) | VAF 50/484 reads (10%) | called by mutect2, pindel
- MYRFL | c.1033T>A p.F345I | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR8B3 | c.712T>G p.F238V | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- PCDH9 | c.3437C>A p.P1146H (on ENST00000377865 / NM_203487.3; = p.P1112H on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/396 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PHC3 | c.2885C>G p.A962G (on ENST00000494943 / NM_001308116.2; = p.A974G on NM_024947.4) | Missense Mutation (SNP) | VAF 55/366 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- PTER | c.979A>G p.R327G | Missense Mutation (SNP) | VAF 11/364 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- PTPRT | c.2527C>T p.L843F | Missense Mutation (SNP) | VAF 95/471 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- PURA | c.154_159del p.G52_G53del | In Frame Del (DEL) | VAF 32/244 reads (13%) | called by pindel, varscan2
- RALGAPA2 | c.4771C>A p.Q1591K | Missense Mutation (SNP) | VAF 15/403 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- RWDD2B | c.652T>G p.F218V | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SATL1 | c.1314A>T p.Q438H (on ENST00000395409; = p.Q625H on NM_001012980.2) | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SMG1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- SPATA13 | c.930G>C p.E310D | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TCF25 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 73/327 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- UMPS | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USPL1 | c.865A>G p.K289E | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2
- VAX1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 97/424 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- WASHC2A | c.1556T>A p.L519* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | called by muse, varscan2
- WNT9A | c.96G>T p.G32= | Splice Region (SNP) | VAF 85/307 reads (28%) | called by muse, mutect2, varscan2
- ZNF326 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 20/299 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF492 | c.1188A>C p.E396D | Missense Mutation (SNP) | VAF 48/409 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF572 | c.1523C>A p.T508N | Missense Mutation (SNP) | VAF 81/695 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ZZZ3 | c.2413A>G p.K805E | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ACTA1 | c.756C>T p.I252= | Silent (SNP) | VAF 14/432 reads (3%) | catalogued as COSV64202830, COSV64203612, COSV64203943; called by muse, mutect2
- ADAMTS14 | c.3333G>T p.L1111= | Silent (SNP) | VAF 71/523 reads (14%) | catalogued as COSV100941432; called by muse, mutect2, varscan2
- AMY2A | c.1182C>A p.G394= | Silent (SNP) | VAF 44/796 reads (6%) | called by muse, mutect2
- DISC1 | c.1542T>G p.G514= | Silent (SNP) | VAF 170/536 reads (32%) | called by muse, mutect2, varscan2
- GALNT5 | c.834T>C p.F278= | Silent (SNP) | VAF 34/244 reads (14%) | called by muse, varscan2
- GGT5 | c.1302A>G p.R434= | Silent (SNP) | VAF 49/349 reads (14%) | called by muse, mutect2, varscan2
- GLB1L3 | c.1266C>T p.D422= | Silent (SNP) | VAF 26/372 reads (7%) | catalogued as rs563534960, COSV68393532; called by muse, mutect2
- GPC5 | c.654C>T p.S218= | Silent (SNP) | VAF 71/359 reads (20%) | catalogued as rs1452657655; called by muse, mutect2, varscan2
- GRIA1 | c.2346C>T p.Y782= | Silent (SNP) | VAF 21/279 reads (8%) | catalogued as rs1297353880; called by muse, mutect2
- HELZ2 | c.822G>A p.G274= | Silent (SNP) | VAF 88/617 reads (14%) | called by muse, mutect2, varscan2
- HS3ST4 | c.204G>A p.S68= | Silent (SNP) | VAF 99/496 reads (20%) | called by muse, mutect2, varscan2
- INPP5D | c.2832C>T p.Y944= (on ENST00000445964 / NM_001017915.3; = p.Y943= on NM_005541.5) | Silent (SNP) | VAF 92/518 reads (18%) | catalogued as rs777512099, COSV104422267; called by muse, mutect2, varscan2
- IQGAP3 | c.2979G>A p.L993= | Silent (SNP) | VAF 36/454 reads (8%) | called by muse, mutect2
- KCNK10 | c.1089C>T p.H363= | Silent (SNP) | VAF 109/451 reads (24%) | catalogued as rs201640910, COSV56641254; called by muse, mutect2, varscan2
- KCNV1 | c.246C>T p.A82= | Silent (SNP) | VAF 63/508 reads (12%) | catalogued as rs559355620; called by muse, mutect2, varscan2
- LAMA1 | c.7414A>C p.R2472= | Silent (SNP) | VAF 58/267 reads (22%) | called by muse, mutect2, varscan2
- LRFN1 | c.1269G>A p.A423= | Silent (SNP) | VAF 46/460 reads (10%) | catalogued as COSV99952653; called by muse, mutect2, varscan2
- MAGI2 | c.1281C>A p.T427= | Silent (SNP) | VAF 47/362 reads (13%) | catalogued as COSV62661985; called by muse, mutect2, varscan2
- MAST4 | c.5919G>A p.S1973= (on ENST00000403625 / NM_001164664.2; = p.S1784= on NM_015183.3) | Silent (SNP) | VAF 76/432 reads (18%) | catalogued as COSV55134656; called by muse, mutect2, varscan2
- NACC2 | c.804C>T p.D268= | Silent (SNP) | VAF 142/527 reads (27%) | catalogued as rs1159494031; called by muse, mutect2, varscan2
- NRG1 | c.658A>C p.R220= | Silent (SNP) | VAF 21/320 reads (7%) | called by muse, mutect2
- NT5DC3 | c.303C>T p.F101= | Silent (SNP) | VAF 64/327 reads (20%) | catalogued as rs752977542, COSV67322839; called by muse, mutect2, varscan2
- OR2T2 | c.759C>T p.Y253= | Silent (SNP) | VAF 150/478 reads (31%) | catalogued as rs763553843, COSV61618280; called by muse, varscan2
- OR4K5 | c.201C>A p.S67= | Silent (SNP) | VAF 30/261 reads (11%) | called by muse, mutect2, varscan2
- PEG3 | c.3477A>T p.G1159= | Silent (SNP) | VAF 41/295 reads (14%) | called by muse, mutect2, varscan2
- PURG | c.33C>T p.G11= | Silent (SNP) | VAF 10/325 reads (3%) | called by muse, mutect2
- RYR3 | c.1119T>G p.T373= | Silent (SNP) | VAF 33/334 reads (10%) | catalogued as COSV101212027, COSV101215037, COSV66780594; called by muse, mutect2
- STRIP1 | c.1947G>A p.A649= | Silent (SNP) | VAF 33/244 reads (14%) | catalogued as rs780867138; called by muse, mutect2, varscan2
- TIGD5 | c.1920C>T p.D640= | Silent (SNP) | VAF 97/676 reads (14%) | catalogued as rs368341139; called by muse, mutect2, varscan2
- TRIM77 | c.1146A>G p.K382= | Silent (SNP) | VAF 29/391 reads (7%) | catalogued as rs1286552345; called by muse, mutect2
- ZFPM2 | c.2160G>A p.R720= | Silent (SNP) | VAF 34/388 reads (9%) | catalogued as rs752762729, COSV65873944; called by muse, mutect2
- ZNF516 | c.1419G>A p.A473= | Silent (SNP) | VAF 46/378 reads (12%) | called by muse, mutect2, varscan2
- ZNF565 | c.1281C>T p.G427= (on ENST00000355114; = p.G387= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 94/410 reads (23%) | catalogued as rs745721434, COSV58410700; called by muse, mutect2, varscan2
- ARHGAP33 | c.1943-21C>T | Intron (SNP) | VAF 22/534 reads (4%) | called by muse, mutect2
- FBLN1 | c.1698-11399G>A | Intron (SNP) | VAF 49/419 reads (12%) | catalogued as rs11551; called by muse, mutect2, varscan2
- NDUFA9 | c.897-84G>T | Intron (SNP) | VAF 43/332 reads (13%) | called by muse, mutect2, varscan2
- NEDD4L | c.297+4643C>T | Intron (SNP) | VAF 25/364 reads (7%) | catalogued as rs959482655; called by muse, mutect2
